Surgical pathology report (de-identified scan), TCGA case TCGA-HQ-A2OF, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HQ-A2OF-01A (Primary Tumor).

hw 9/16/11

Sample Type Tumour Primary

Sample Preparation

Fresh Frozen

Site of Primary (Event)

Bladder

Site of Tissue

BLADDER

Year of Sample Collection

ICD-0-3

Age at Sample Collection (yrs)

adenocarcinoma, papillary, NOS 8260/3
Site: bladder, dome C67.1

Sample Comments

Days to Procedure Date

0

Days to Diagnosis

11

Type of Procedure

Surgical resection

Site of Primary (Histology)

BLADDER - DOME

Bilateral Disease

Tumour Size (cm)

5

Histology

Focally papillary adenocarcinoma

Grade/Differentiation

Grade II (Moderately differentiated)

Pathological T

T3b

Pathological N

N0

Number of Nodes Sampled

Number of Nodes Positive

Clinical M

MX

Histology Comments

Source: NCI Genomic Data Commons file 114af562-89ff-4819-86db-c926b268e7c6 (TCGA-HQ-A2OF.255B8E38-1BBF-4B3B-B3C6-99F5A41779EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).